CCDI case PBCCCI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/15d3fe9d-b131-45cc-b53a-3f001966e058

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 17.5 years (6,402 days).

Biospecimens (3 samples)
- Sample 0DO2ER: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DO2EY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DO2F9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
